TCGA case TCGA-B9-4114 — Kidney Renal Papillary Cell Carcinoma (TCGA-KIRP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: UNC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/df135722-b98d-4dec-906d-77da13df39b9

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 49 years; Vital status: Alive.

Diagnoses (2)
1. Papillary adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8260/3; ICD-10 code: C64.1; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 49.3 years (17,989 days); Year of diagnosis: 2009; AJCC staging edition: 6th; AJCC clinical T: T2; AJCC clinical N: N0; AJCC clinical M: M1; AJCC clinical stage: Stage IV; AJCC pathologic T: T2; AJCC pathologic N: NX; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 857 days (2.3 years).
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Pazopanib Hydrochloride; Days to treatment start: 722 days (2.0 years); Days to treatment end: 755 days (2.1 years); Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Sunitinib; Days to treatment start: 779 days (2.1 years); Treatment outcome: Treatment Ongoing.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 51.0 years (18,626 days); Days to diagnosis: 637 days (1.7 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.

Follow-up (3 entries)
- Day 637 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 857 days (2.3 years); Disease response: With Tumor.
- Follow-up contact recording only the day: day 21.

Molecular and laboratory tests
- Leukocytes: Normal.
- Platelets: Normal.
- Calcium: Normal.
- Hemoglobin: Low.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 76 kg; Height: 175 cm; BMI: 24.8.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 30; Tobacco smoking onset year: 1989; Tobacco smoking quit year: 2009.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-B9-4114-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.9; Intermediate dimension: 0.7; Shortest dimension: 0.3.
  Slide TCGA-B9-4114-01A-01-BS1: Section location: Bottom; Percent tumor cells: 78; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 20.
  Slide TCGA-B9-4114-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20.
- Sample TCGA-B9-4114-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-B9-4114-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Papillary Renal Cell Carcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Hemoglobin level: Low; Lymph nodes examined: No; Tobacco smoking history indicator: 4.
- Drug treatment 1: Pharmaceutical therapy drug name: Votrient.
- Follow-up form 2: Tumor status: With tumor; New tumor event pharmaceutical treatment: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 857 days; disease-specific survival: no event (censored), 857 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 637 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-B9-4114-01A-01D-1190-01): tumor purity 0.65, ploidy 2.28, whole-genome doublings 0.
